TCGA case TCGA-EE-A2ML — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/01cfbfae-f344-439d-aeab-a9e15d636325

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 35 years; Vital status: Dead; Days to death: 6,590 days (18.0 years).

Diagnoses (22)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: Progression; Age at diagnosis: 43.6 years (15,912 days); Days to diagnosis: 2,772 days (7.6 years); Prior treatment: No; Days to last follow up: 6,590 days (18.0 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: III; Sites of involvement: Skin, Trunk; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >2.0-4.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 36.0 years (13,140 days); Year of diagnosis: 1994; AJCC staging edition: 4th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Dacarbazine; Days to treatment start: 5,973 days (16.4 years); Days to treatment end: 6,156 days (16.9 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fotemustine; Days to treatment start: 6,279 days (17.2 years); Days to treatment end: 6,339 days (17.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Ontuxizumab; Days to treatment start: 6,355 days (17.4 years); Days to treatment end: 6,440 days (17.6 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
4. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Bone, NOS. Age at diagnosis: 49.6 years (18,123 days); Days to diagnosis: 4,983 days (13.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 5,003 days (13.7 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
5. Recurrence of diagnosis 3 (Malignant melanoma, NOS). Age at diagnosis: 51.4 years (18,762 days); Days to diagnosis: 5,622 days (15.4 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
6. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lower limb, NOS. Age at diagnosis: 52.0 years (18,991 days); Days to diagnosis: 5,851 days (16.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
7. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Head, face or neck, NOS. Age at diagnosis: 52.0 years (18,991 days); Days to diagnosis: 5,851 days (16.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
8. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Small intestine, NOS. Age at diagnosis: 52.0 years (18,991 days); Days to diagnosis: 5,851 days (16.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 5,921 days (16.2 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
9. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Pelvis, NOS. Age at diagnosis: 52.0 years (18,991 days); Days to diagnosis: 5,851 days (16.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
10. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Abdomen, NOS. Age at diagnosis: 52.0 years (18,991 days); Days to diagnosis: 5,851 days (16.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
11. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Upper limb, NOS. Age at diagnosis: 52.0 years (18,991 days); Days to diagnosis: 5,851 days (16.0 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
12. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Peritoneum, NOS. Age at diagnosis: 52.2 years (19,061 days); Days to diagnosis: 5,921 days (16.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 5,921 days (16.2 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
13. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Abdomen, NOS. Age at diagnosis: 52.3 years (19,104 days); Days to diagnosis: 5,964 days (16.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
14. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Intra-abdominal lymph nodes. Age at diagnosis: 52.9 years (19,305 days); Days to diagnosis: 6,165 days (16.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 6,218 days (17.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
15. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Liver. Age at diagnosis: 53.0 years (19,350 days); Days to diagnosis: 6,210 days (17.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
16. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Small intestine, NOS. Age at diagnosis: 53.0 years (19,350 days); Days to diagnosis: 6,210 days (17.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 6,218 days (17.0 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
17. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 53.0 years (19,350 days); Days to diagnosis: 6,210 days (17.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
18. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Intrathoracic lymph nodes. Age at diagnosis: 53.0 years (19,350 days); Days to diagnosis: 6,210 days (17.0 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
19. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Parotid gland. Age at diagnosis: 53.1 years (19,389 days); Days to diagnosis: 6,249 days (17.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 6,253 days (17.1 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
20. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Connective, subcutaneous and other soft tissues of abdomen. Age at diagnosis: 53.1 years (19,411 days); Days to diagnosis: 6,271 days (17.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
21. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Head, face or neck, NOS. Age at diagnosis: 53.8 years (19,645 days); Days to diagnosis: 6,505 days (17.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 6,505 days (17.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
22. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Small intestine, NOS. Age at diagnosis: 53.8 years (19,665 days); Days to diagnosis: 6,525 days (17.9 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (21 entries)
- Day 4,983 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 4,983 days (13.6 years).
- Day 5,622 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 5,622 days (15.4 years).
- Day 5,851 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Upper limb, NOS; Days to progression: 5,851 days (16.0 years).
- Day 5,851 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Small intestine, NOS; Days to progression: 5,851 days (16.0 years).
- Day 5,851 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvis, NOS; Days to progression: 5,851 days (16.0 years).
- Day 5,851 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Head, face or neck, NOS; Days to progression: 5,851 days (16.0 years).
- Day 5,851 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lower limb, NOS; Days to progression: 5,851 days (16.0 years).
- Day 5,851 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 5,851 days (16.0 years).
- Day 5,921 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Peritoneum, NOS; Days to progression: 5,921 days (16.2 years).
- Day 5,964 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 5,964 days (16.3 years).
- Day 6,165 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intra-abdominal lymph nodes; Days to progression: 6,165 days (16.9 years).
- Days to follow up: 6,176 days (16.9 years); Disease response: With Tumor.
- Day 6,210 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Small intestine, NOS; Days to progression: 6,210 days (17.0 years).
- Day 6,210 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 6,210 days (17.0 years).
- Day 6,210 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Intrathoracic lymph nodes; Days to progression: 6,210 days (17.0 years).
- Day 6,210 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 6,210 days (17.0 years).
- Day 6,249 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Parotid gland; Days to progression: 6,249 days (17.1 years).
- Day 6,271 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues of abdomen; Days to progression: 6,271 days (17.2 years).
- Day 6,505 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Head, face or neck, NOS; Days to progression: 6,505 days (17.8 years).
- Day 6,525 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Small intestine, NOS; Days to progression: 6,525 days (17.9 years).
- Days to follow up: 6,590 days (18.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A2ML-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A2ML-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
  Slide TCGA-EE-A2ML-06A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A2ML-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 3; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 8; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: MORAb-004; Clinical trial drug classification: immunotherapy; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 6,590 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 6,590 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 4,983 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A2ML-06A-11D-A191-01): tumor purity 0.62, ploidy 2.12, whole-genome doublings 0.
